Gene-level copy-number profile of tumor specimen TCGA-28-5208-01A from TCGA case TCGA-28-5208, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.2 years (19,053 days).
Specimen TCGA-28-5208-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.726e7157-ca54-4ae4-b85e-0b6fbf96ceb6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-5208-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e5206aa3-0346-45b3-b788-d08861477791

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 7,105; copy number 2: 48,455; copy number 3: 3,411; copy number 4: 87; copy number 5: 1; copy number 6: 435; copy number 8: 14; copy number 11: 14; copy number 13: 23; copy number 19: 164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-28-5208-01A-01D-1479-01): tumor purity 0.87, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–1): FOCAD.
- chr9:20,786,927–27,610,745, 105 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 651 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:26,667,068–62,275,678, 650 genes, copy number 6–19 (within-gene range 4–19) (broad region; genes not listed).
- chr7:79,657,947–79,675,015, 1 gene, copy number 5 (within-gene range 3–5): AC073048.1.

Autosomal genes at a single copy (total copy number 1): 4,718. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
